Somatic mutation profile of tumor specimen TCGA-56-A5DR-01A (aliquot TCGA-56-A5DR-01A-11D-A27K-08) from TCGA case TCGA-56-A5DR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.7 years (29,828 days).
Specimen TCGA-56-A5DR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d68550e5-a52d-462e-9b7c-b45f79d632ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A5DR-10A (Blood Derived Normal), aliquot TCGA-56-A5DR-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ac932da-2b89-480c-bade-b01d2a3b0e6e

The open-access MAF lists 1,194 somatic variants for this specimen: 878 protein-altering or splice-affecting, 290 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 751, Silent 290, Nonsense Mutation 96, Frame Shift Del 13, Intron 10, RNA 10, Splice Site 9, 5'UTR 3, Splice Region 3, Translation Start Site 2, Frame Shift Ins 2, Nonstop Mutation 2.

Variants (750 of 1,194; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CIC | c.2974C>T p.Q992* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as rs1135401825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.12592C>T p.R4198* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as rs587783685, CM122102, COSV56409006, COSV56429446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519739, COSV61684417, COSV61684645, COSV61684738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV56017770; called by muse, varscan2
- ADAMTS10 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs577890480, COSV54356968; called by muse, mutect2
- ADCY6 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs767572682; called by muse, mutect2, varscan2
- ADGRA3 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs774236322; called by muse, mutect2, varscan2
- ADGRB2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57078119; called by muse, mutect2, varscan2
- ADNP | c.2919G>C p.E973D | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as COSV62425864; called by muse, mutect2, varscan2
- ADRB3 | c.213G>T p.M71I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV61462388; called by muse, mutect2, varscan2
- AGBL5 | c.1886T>A p.V629D | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); catalogued as COSV59935426; called by muse, mutect2, varscan2
- AHR | c.2409G>C p.Q803H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV54122681; called by muse, mutect2, varscan2
- AIFM2 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV57158731; called by muse, mutect2, varscan2
- AL441992.2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs754242611; called by muse, mutect2, varscan2
- ALB | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55741615; called by muse, mutect2
- ALX4 | c.648del p.N217Tfs*33 | Frame Shift Del (DEL) | VAF 75/239 reads (31%) | catalogued as COSV61324622; called by mutect2, pindel, varscan2
- ANKFN1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs1438932878; called by muse, mutect2, varscan2
- ANKRD17 | c.3169C>G p.P1057A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV58221502; called by muse, mutect2, varscan2
- ANKRD35 | c.2148G>C p.R716S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100841710; called by muse, mutect2, varscan2
- ARHGAP31 | c.2848C>T p.R950C | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs199928704; called by muse, varscan2
- ARHGAP32 | c.3304C>T p.R1102* (on ENST00000310343 / NM_001378025.1; = p.R753* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 25/202 reads (12%) | catalogued as COSV104403863; called by muse, mutect2, varscan2
- ARPP21 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761602901, COSV51797081; called by muse, mutect2, varscan2
- ARPP21 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.343); catalogued as COSV51803252; called by muse, mutect2, varscan2
- ASTN1 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV56083103, COSV99920980; called by muse, mutect2, varscan2
- ATAD5 | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as rs757452567; called by muse, mutect2, varscan2
- ATP10A | c.1200C>A p.D400E | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV63518587; called by muse, mutect2, varscan2
- ATP2A1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs778710343; called by muse, mutect2, varscan2
- BCLAF1 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV62142019, COSV62145966; called by muse, mutect2, varscan2
- BCLAF3 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV61413453; called by muse, mutect2, varscan2
- BIRC6 | c.12429C>G p.I4143M | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs558289228, COSV70199300; called by muse, mutect2, varscan2
- BMPR2 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as CX1514012; called by muse, mutect2, varscan2
- BMPR2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65808936; called by muse, mutect2, varscan2
- BORCS5 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1322659319; called by muse, mutect2, varscan2
- BRIP1 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV104386451; called by muse, mutect2, varscan2
- C1RL | c.1458G>C p.K486N | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV56923995; called by muse, mutect2, varscan2
- C1orf158 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as rs776101071, COSV55348032; called by muse, mutect2, varscan2
- C4orf17 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV58512410; called by mutect2, varscan2
- CACNA1C | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100214579; called by muse, varscan2
- CACNA1C | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as rs1555832946; called by muse, varscan2
- CACNA1C | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 68/177 reads (38%) | catalogued as rs1555962719; called by muse, mutect2, varscan2
- CASKIN2 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778805420; called by muse, mutect2, varscan2
- CCDC87 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs762394264, COSV59579483, COSV59579788; called by muse, mutect2, varscan2
- CCER1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 32/146 reads (22%) | catalogued as COSV100726901; called by muse, mutect2, varscan2
- CCL27 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs777698595, COSV52404933; called by muse, mutect2, varscan2
- CD300LB | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100075566; called by muse, varscan2
- CD300LB | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100075547, COSV58726911; called by muse, varscan2
- CDH11 | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99217881, COSV99218614; called by muse, mutect2, varscan2
- CDH13 | c.509G>T p.R170M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.361); catalogued as COSV51841354; called by muse, mutect2, varscan2
- CDH18 | c.2276A>C p.Q759P | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as rs1438007756; called by muse, mutect2, varscan2
- CDH8 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54868005; called by muse, mutect2, varscan2
- CDK12 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71000145; called by muse, mutect2, varscan2
- CDKN2A | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM083605, COSV100448493, COSV58690485; called by muse, mutect2, varscan2
- CEP20 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as rs147959689; called by muse, mutect2, varscan2
- CEP70 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs942378419; called by muse, mutect2, varscan2
- CEP78 | c.966G>C p.W322C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV52845293; called by muse, mutect2, varscan2
- CERS3 | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1398188381; called by muse, mutect2, varscan2
- CFTR | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM920194; called by muse, mutect2, varscan2
- CHRNA7 | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV60971936; called by muse, mutect2, varscan2
- CIC | c.3821C>T p.S1274L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs755072565; called by muse, mutect2, varscan2
- CLEC1A | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as rs1168906993, COSV59534031; called by muse, mutect2, varscan2
- CLECL1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as rs1259319683; called by muse, mutect2, varscan2
- CLIC5 | c.742G>T p.E248* (on ENST00000185206 / NM_001370649.1; = p.E89* on NM_016929.5) | Nonsense Mutation (SNP) | VAF 33/147 reads (22%) | catalogued as COSV51760117; called by muse, mutect2, varscan2
- CLIP1 | c.1661C>G p.S554C (on ENST00000620786 / NM_001247997.1; = p.S543C on NM_002956.2) | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV100211431; called by muse, mutect2, varscan2
- CLPX | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55646937; called by muse, mutect2, varscan2
- CLRN2 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV55551589; called by muse, mutect2, varscan2
- CLSPN | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.96); catalogued as COSV52049566; called by muse, mutect2, varscan2
- CNTNAP4 | c.2591C>T p.S864L | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs775109304; called by muse, mutect2
- COL15A1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs757515988; called by muse, mutect2, varscan2
- COL22A1 | c.4393C>G p.R1465G | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV57334771; called by muse, mutect2, varscan2
- COL4A4 | c.3859C>G p.L1287V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.652); catalogued as rs571869797; called by muse, mutect2, varscan2
- COL9A1 | c.2008G>C p.G670R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57882797; called by muse, mutect2, varscan2
- COP1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100442836; called by muse, mutect2, varscan2
- CPXM2 | c.1748A>G p.N583S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs375460068; called by muse, mutect2, varscan2
- CRYZ | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234662736; called by muse, mutect2, varscan2
- CSRNP3 | c.1534G>C p.G512R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.041); catalogued as COSV100084955; called by muse, mutect2, varscan2
- CTC1 | c.3523C>T p.R1175W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs747504166; called by muse, mutect2, varscan2
- CTNND2 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58936634; called by muse, mutect2, varscan2
- CTSB | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775321729, COSV61540736; called by muse, mutect2, varscan2
- DCAF13 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1421870829, COSV52572009; called by muse, mutect2, varscan2
- DCAF4L2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV60478305; called by muse, mutect2, varscan2
- DCSTAMP | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV52577466; called by muse, mutect2, varscan2
- DDB2 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1451839702; called by muse, mutect2, varscan2
- DDX3X | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV101302370, COSV67863415; called by muse, mutect2, varscan2
- DDX42 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs201845056; called by muse, mutect2, varscan2
- DENND2D | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 90/277 reads (32%) | catalogued as COSV100718680; called by muse, mutect2, varscan2
- DSG1 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV57136807; called by muse, mutect2, varscan2
- DST | c.12045G>T p.Q4015H (on ENST00000361203 / NM_001374722.1; = p.Q1603H on NM_015548.5) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99757705; called by muse, mutect2, varscan2
- DST | c.8770G>C p.E2924Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99749655; called by muse, mutect2, varscan2
- DUSP12 | c.236T>C p.F79S | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1194072322; called by muse, mutect2, varscan2
- EFNA5 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV60948382; called by muse, mutect2, varscan2
- EIF3A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64960550; called by muse, mutect2, varscan2
- ELP1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs755988042; called by muse, mutect2, varscan2
- EMC1 | c.1846C>A p.P616T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV64345707; called by muse, mutect2, varscan2
- EP400 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs1298036844, COSV57772745; called by muse, mutect2, varscan2
- EPX | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1003830294, COSV56594781; called by muse, mutect2, varscan2
- ERBB3 | c.3962C>T p.S1321F | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV57255943; called by muse, mutect2, varscan2
- EXOC8 | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99150094; called by muse, mutect2, varscan2
- EYA2 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100426692; called by muse, varscan2
- FAM241A | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV59038042; called by muse, mutect2, varscan2
- FAM83C | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | catalogued as COSV65582839; called by muse, mutect2, varscan2
- FAT1 | c.11737G>A p.A3913T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs773650405, COSV101499198; called by muse, mutect2, varscan2
- FAT4 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV67894837; called by muse, mutect2, varscan2
- FIGNL1 | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV63553267; called by muse, mutect2, varscan2
- FLG | c.6922G>C p.E2308Q | Missense Mutation (SNP) | VAF 98/710 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as rs752194201, COSV64245274; called by muse, mutect2, varscan2
- FLG | c.5411C>T p.S1804L | Missense Mutation (SNP) | VAF 101/515 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs370091685; called by muse, mutect2, varscan2
- FMO1 | c.1215G>C p.M405I | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100707843; called by muse, mutect2, varscan2
- FOXB1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV68525564; called by mutect2, varscan2
- FOXC1 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1037043441; called by muse, mutect2, varscan2
- FRG1 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56999200; called by muse, mutect2, varscan2
- FTL | c.108C>G p.F36L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs1431684706; called by muse, varscan2
- GABRA4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51934174; called by muse, mutect2, varscan2
- GABRG3 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61516251, COSV61530362; called by muse, mutect2, varscan2
- GALNT15 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs149803620; called by muse, mutect2, varscan2
- GALNT17 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100353469; called by muse, mutect2, varscan2
- GCSAML | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV63579791; called by muse, mutect2, varscan2
- GFRAL | c.1122-1G>A p.X374_splice | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as COSV61229627; called by muse, mutect2, varscan2
- GGT6 | c.863C>T p.S288L (on ENST00000574154 / NM_001122890.3; = p.S256L on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs764779382, COSV54596236, COSV54605784; called by muse, mutect2, varscan2
- GJA8 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV53788690; called by muse, mutect2, varscan2
- GLB1L | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs773330205; called by muse, mutect2, varscan2
- GLG1 | c.1509G>C p.L503F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753311750; called by muse, mutect2, varscan2
- GOLGB1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV61467620; called by muse, mutect2, varscan2
- GPR155 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV55041219; called by muse, mutect2, varscan2
- GPR63 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV57741350; called by muse, mutect2, varscan2
- GRIN2A | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV58061758; called by muse, mutect2, varscan2
- GRM7 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781746536; called by muse, mutect2, varscan2
- GRM8 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100282447; called by muse, mutect2
- H2AC6 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100019793; called by muse, mutect2, varscan2
- HCN1 | c.1496G>C p.G499A | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV57508108; called by muse, mutect2, varscan2
- HCN1 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV57533736, COSV57539644; called by muse, mutect2, varscan2
- HECW1 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.011); catalogued as rs767968550, COSV67822712, COSV67830331, COSV99060294; called by muse, mutect2, varscan2
- HGD | c.898G>T p.V300L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs886905654; called by muse, mutect2, varscan2
- HOXA3 | c.747T>A p.D249E | Missense Mutation (SNP) | VAF 112/202 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100415283; called by muse, mutect2, varscan2
- HRG | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV51648453; called by muse, mutect2, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- HTR1B | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100885362; called by muse, mutect2, varscan2
- IFT80 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as rs1435981814, COSV58445592, COSV58448261; called by muse, mutect2
- INPP5F | c.3109C>G p.Q1037E | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.006); catalogued as rs1564860063, COSV100739934; called by muse, mutect2, varscan2
- IPP | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111816962; called by muse, mutect2, varscan2
- IRS1 | c.1154C>A p.S385* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | catalogued as COSV59335187; called by muse, mutect2, varscan2
- ISG20L2 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.886); catalogued as COSV57460021; called by muse, mutect2, varscan2
- JAG2 | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1225312355; called by muse, mutect2, varscan2
- JAG2 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780967753; called by muse, mutect2, varscan2
- KCNJ14 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100655818; called by muse, mutect2, varscan2
- KCNK1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs199630093, COSV64034520; called by muse, mutect2
- KCNK2 | c.606del p.G203Efs*46 (on ENST00000444842 / NM_001017425.3; = p.G188Efs*46 on NM_014217.4) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as COSV67210460; called by mutect2, pindel, varscan2
- KCNK6 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371310407; called by muse, mutect2, varscan2
- KIF2B | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99275406; called by muse, mutect2, varscan2
- KLF7 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as COSV100519324, COSV58744828; called by muse, mutect2, varscan2
- KMT2A | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.602); catalogued as rs1555138708; called by muse, mutect2, varscan2
- KMT2A | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781787241; called by muse, mutect2, varscan2
- KRCC1 | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 40/135 reads (30%) | catalogued as COSV61251856; called by muse, mutect2, varscan2
- KRT12 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52429823; called by muse, mutect2, varscan2
- KRT222 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV67497937; called by muse, mutect2
- KRTAP13-3 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs780864048; called by muse, mutect2, varscan2
- KRTAP4-3 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV66940646; called by muse, mutect2, varscan2
- KRTAP5-9 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1269502670, COSV73200182, COSV73200258; called by muse, mutect2, varscan2
- KSR1 | c.1813del p.V605Cfs*25 (on ENST00000644974 / NM_001367810.1; = p.V490Cfs*25 on NM_014238.2) | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs766479551; called by mutect2, pindel
- L2HGDH | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as COSV55560706; called by muse, mutect2, varscan2
- LAMA2 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.18); catalogued as rs868408509; called by muse, mutect2
- LAMA2 | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149993931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.3679G>T p.D1227Y | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.417); catalogued as COSV70346459; called by muse, mutect2
- LAMA2 | c.7858G>A p.D2620N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70337004; called by muse, mutect2, varscan2
- LAMC1 | c.4657G>T p.D1553Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV51161332; called by muse, mutect2, varscan2
- LAMP3 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1369423682, COSV55614133; called by muse, mutect2, varscan2
- LCP1 | c.1404G>C p.K468N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59940326, COSV59941480; called by muse, varscan2
- LIN7A | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99691594; called by muse, mutect2, varscan2
- LPAR1 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV62691064; called by muse, mutect2, varscan2
- LRP1B | c.12493C>T p.H4165Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV67201125, COSV67210387, COSV67261032; called by muse, mutect2, varscan2
- MAGEL2 | c.2837G>T p.W946L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100046258; called by muse, mutect2, varscan2
- MAP3K6 | c.3517A>G p.T1173A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs749748588; called by muse, mutect2, varscan2
- MAPK8 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827582; called by muse, mutect2, varscan2
- MARCHF6 | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV56884130; called by muse, mutect2, varscan2
- MBD6 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV63072983; called by muse, mutect2, varscan2
- MCM7 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 177/644 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs749934918, COSV57997360; called by muse, mutect2, varscan2
- MFN1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs748002076; called by muse, mutect2, varscan2
- MGAT3 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV57864375, COSV57865845; called by muse, mutect2
- MME | c.1463C>A p.S488* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV64706515; called by muse, mutect2, varscan2
- MRPL4 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV53449375; called by muse, mutect2, varscan2
- MRPL40 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs147952957; called by muse, mutect2, varscan2
- MSH3 | c.2889C>G p.I963M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as COSV54158957; called by muse, mutect2, varscan2
- MUC17 | c.6248C>G p.S2083* | Nonsense Mutation (SNP) | VAF 55/383 reads (14%) | catalogued as COSV60287535, COSV60288549; called by muse, mutect2, varscan2
- MUC2 | c.1909C>G p.R637G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs762582021; called by muse, mutect2, varscan2
- MUC4 | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.318); catalogued as COSV62197683; called by muse, mutect2
- MUC5B | c.14437C>G p.L4813V | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV71592926; called by muse, mutect2, varscan2
- MYBPH | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751018911; called by muse, mutect2, varscan2
- MYO5B | c.3016C>T p.H1006Y | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs888019349; called by muse, mutect2, varscan2
- MYT1 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60503659; called by muse, mutect2
- N4BP2L2 | c.2282C>G p.S761* (on ENST00000674422; = p.S332* on NM_033111.4) | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100678706; called by muse, mutect2
- NCAPG2 | c.2290A>G p.I764V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1043232107, COSV51992018; called by muse, mutect2, varscan2
- NCKIPSD | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs145562243; called by muse, mutect2, varscan2
- NCOA6 | c.3416A>C p.E1139A | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV62861963; called by muse, mutect2, varscan2
- NEDD4 | c.2038G>A p.E680K (on ENST00000508342 / NM_001284338.1; = p.E261K on NM_006154.4) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs1382856818; called by muse, mutect2, varscan2
- NINL | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV54007092; called by muse, mutect2, varscan2
- NKX6-1 | c.884A>G p.H295R | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs754561780; called by muse, mutect2, varscan2
- NLRP9 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV60467676; called by muse, mutect2, varscan2
- NMUR1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs531895755; called by muse, mutect2, varscan2
- NOCT | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.042); catalogued as COSV99763983; called by muse, mutect2, varscan2
- NPR1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs1331090381; called by muse, mutect2, varscan2
- NRSN1 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65894073; called by muse, mutect2, varscan2
- NT5DC1 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.079); catalogued as rs200437402, COSV60308721; called by muse, mutect2, varscan2
- OR10G7 | c.489C>G p.F163L | Missense Mutation (SNP) | VAF 47/547 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57868895; called by muse, mutect2
- OR11G2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs762702987, COSV62132026; called by muse, mutect2, varscan2
- OR11H1 | c.884G>T p.S295I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1057208965; called by mutect2, varscan2
- OR11L1 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63315093; called by muse, mutect2, varscan2
- OR2M7 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV58738036, COSV58740807; called by muse, mutect2, varscan2
- OR2T10 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57896714; called by muse, mutect2, varscan2
- OR2T10 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1389591383; called by muse, mutect2, varscan2
- OR4F6 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV61026482; called by muse, mutect2, varscan2
- OR4K2 | c.800C>G p.T267R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV53849706, COSV53850667; called by muse, mutect2, varscan2
- OR56B1 | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770446313; called by muse, mutect2, varscan2
- OR5F1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV53547353, COSV99558580; called by muse, mutect2, varscan2
- OR5K2 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.232); catalogued as COSV101415988; called by muse, mutect2, varscan2
- OR5P2 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs756334986; called by muse, mutect2, varscan2
- OR6K3 | c.87C>G p.I29M (on ENST00000368146; = p.I13M on NM_001005327.2) | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100933907; called by muse, mutect2
- OR8G5 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV58382335; called by muse, mutect2, varscan2
- OR8H2 | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 49/226 reads (22%) | catalogued as COSV57943444; called by muse, mutect2, varscan2
- OR8K1 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV54403307; called by muse, mutect2, varscan2
- PCDH11Y | c.280C>A p.Q94K (on ENST00000400457 / NM_032973.2; = p.Q83K on NM_032971.3) | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.49); PolyPhen benign (0.123); catalogued as COSV53093687; called by muse, mutect2, varscan2
- PCDHGA4 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs778595998; called by muse, mutect2, varscan2
- PCLO | c.12545C>T p.A4182V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100427232; called by muse, mutect2, varscan2
- PCLO | c.6415G>A p.E2139K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV100433612, COSV61671390; called by muse, mutect2, varscan2
- PDCD4 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV54521614; called by muse, mutect2, varscan2
- PDZD2 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56870225; called by muse, mutect2, varscan2
- PDZD2 | c.5598G>C p.K1866N | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763751546; called by muse, mutect2, varscan2
- PEG3 | c.1169G>C p.R390T | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55632785; called by muse, mutect2, varscan2
- PEG3 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55644097; called by muse, mutect2, varscan2
- PIAS2 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs765901312; called by muse, mutect2, varscan2
- PIGG | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.265); catalogued as rs374780994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIGQ | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs773722943, COSV50321305; called by muse, mutect2, varscan2
- PLCH1 | c.4754G>A p.R1585K (on ENST00000340059 / NM_001130960.2; = p.R1577K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100395703; called by muse, mutect2, varscan2
- PLCH1 | c.3613G>A p.E1205K (on ENST00000340059 / NM_001130960.2; = p.E1197K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.072); catalogued as rs755984531, COSV100398082; called by muse, varscan2
- PLPPR2 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV52262535; called by muse, mutect2, varscan2
- PMEL | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100092929; called by muse, mutect2, varscan2
- PNPLA2 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV100352023; called by muse, mutect2, varscan2
- PNPT1 | c.2137G>C p.D713H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs752550279; called by muse, mutect2, varscan2
- PON3 | c.961G>C p.A321P | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99672210; called by muse, mutect2, varscan2
- PPCS | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs12093021; called by muse, mutect2, varscan2
- PPP2R1B | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100232123; called by muse, mutect2, varscan2
- PRAMEF12 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63216851; called by muse, mutect2, varscan2
- PREX2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1357812958, COSV99906094; called by muse, mutect2, varscan2
- PRKCD | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1553669028; called by muse, mutect2, varscan2
- PRKD3 | c.560-2A>G p.X187_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as rs746325832; called by muse, mutect2, varscan2
- PRKG1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV64766263; called by muse, mutect2, varscan2
- PRLR | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51495371; called by muse, mutect2, varscan2
- PRRC2C | c.1972C>T p.R658W (on ENST00000367742; = p.R656W on NM_015172.4) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761538879; called by muse, mutect2, varscan2
- PSD | c.1675C>A p.Q559K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99192326; called by muse, mutect2, varscan2
- PTGER3 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as rs369540225; called by muse, mutect2, varscan2
- PTPRS | c.4972G>T p.A1658S | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53636031; called by muse, mutect2, varscan2
- PWP1 | c.906C>G p.V302= | Splice Region (SNP) | VAF 27/131 reads (21%) | catalogued as rs376285721; called by muse, mutect2, varscan2
- RAB26 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146753917; called by muse, mutect2, varscan2
- RAI14 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 85/132 reads (64%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs766617650; called by muse, mutect2, varscan2
- RANBP3L | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56958571; called by muse, mutect2, varscan2
- RASA1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.544); catalogued as COSV99169843; called by muse, mutect2, varscan2
- RBL1 | c.2053C>G p.P685A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60331762; called by muse, mutect2, varscan2
- RBL2 | c.3368C>G p.S1123C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs1370956373; called by muse, mutect2, varscan2
- RGL1 | c.1904C>G p.S635W (on ENST00000360851 / NM_001297672.2; = p.S670W on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1416862285; called by muse, mutect2, varscan2
- RIPK2 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99609642; called by muse, mutect2, varscan2
- RLF | c.4859C>G p.S1620* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV65653239; called by muse, mutect2, varscan2
- RPL10A | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1257230797; called by muse, mutect2, varscan2
- RYR2 | c.8291C>G p.S2764C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769728229; called by muse, mutect2
- S100A2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs566181954; called by muse, mutect2, varscan2
- S1PR3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs745683421; called by muse, mutect2, varscan2
- SAMD13 | c.260G>A p.R87K (on ENST00000370671; = p.R81K on NM_001010971.3) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65744237, COSV65744525; called by muse, mutect2, varscan2
- SBDS | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55888637; called by muse, mutect2
- SCML4 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV64635650; called by muse, mutect2, varscan2
- SCN2A | c.5677T>C p.Y1893H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51831915; called by muse, mutect2, varscan2
- SEC61A1 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54576843; called by muse, mutect2, varscan2
- SENP7 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.023); catalogued as rs1356964274; called by muse, mutect2, varscan2
- SF3B1 | c.2294A>G p.Y765C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59211610; called by muse, mutect2, varscan2
- SGSM3 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs376746554, COSV99960736; called by muse, mutect2
- SLC12A2 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as COSV52475973, COSV99320385; called by muse, mutect2, varscan2
- SLC16A6 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1391087136; called by muse, mutect2, varscan2
- SLC17A3 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57760215; called by muse, mutect2, varscan2
- SLC17A4 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760216618; called by muse, mutect2, varscan2
- SLC28A1 | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs768076441, COSV54478180; called by muse, mutect2, varscan2
- SLC38A8 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305717; called by muse, mutect2
- SLC9A4 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs1310731326; called by muse, mutect2, varscan2
- SORCS1 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99547027; called by muse, mutect2, varscan2
- SORT1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56664738; called by muse, mutect2, varscan2
- SOX2 | c.70A>C p.N24H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs777862989, CD054424, CD070528; called by muse, mutect2, varscan2
- SPAG17 | c.2619G>A p.M873I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV60459056; called by muse, mutect2, varscan2
- SPG7 | c.1582del p.E528Rfs*57 (on ENST00000268704; = p.E535Rfs*57 on NM_003119.4) | Frame Shift Del (DEL) | VAF 49/220 reads (22%) | catalogued as COSV51947737; called by mutect2, pindel, varscan2
- SPOCK2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs949411001, COSV100436383; called by muse, mutect2, varscan2
- SPP1 | c.619G>A p.V207I (on ENST00000395080 / NM_001040058.2; = p.V193I on NM_000582.2) | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs753015454; called by muse, mutect2, varscan2
- SPTLC2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV53641742; called by muse, mutect2, varscan2
- SRGAP1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as COSV61904266; called by muse, mutect2, varscan2
- STIL | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs747628168; called by muse, mutect2
- STX4 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100572998; called by muse, mutect2, varscan2
- STXBP5L | c.3000C>A p.N1000K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs771227041, COSV56499344; called by muse, mutect2, varscan2
- SUGCT | c.1205C>A p.P402Q (on ENST00000335693 / NM_001193313.2; = p.P428Q on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/217 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59354221; called by muse, mutect2, varscan2
- SULT2B1 | c.961C>A p.P321T (on ENST00000201586 / NM_177973.2; = p.P306T on NM_004605.2) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.908); catalogued as rs570769125; called by muse, varscan2
- TAAR5 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs778838635; called by muse, mutect2, varscan2
- TAF1L | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs1404432517; called by muse, mutect2, varscan2
- TAS1R3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765980224, COSV59562128; called by muse, mutect2, varscan2
- TBL1X | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV54280026; called by muse, mutect2, varscan2
- TECRL | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766522427; called by muse, mutect2, varscan2
- TENM3 | c.7682C>T p.T2561M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs1356232786, COSV69302620; called by muse, mutect2
- TEX55 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99817468; called by muse, mutect2, varscan2
- TFPI2 | c.29C>G p.S10W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs745447348; called by muse, mutect2, varscan2
- TGFBR3 | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 32/205 reads (16%) | catalogued as COSV53025203; called by muse, mutect2, varscan2
- THEMIS2 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770560386, COSV100197848; called by muse, mutect2, varscan2
- TIAM1 | c.3945A>T p.V1315= | Splice Region (SNP) | VAF 47/121 reads (39%) | catalogued as COSV99732364; called by muse, mutect2, varscan2
- TMEM132E | c.1036C>T p.R346W (on ENST00000321639; = p.R436W on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs141962331; called by muse, mutect2, varscan2
- TMEM183A | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879072232; called by muse, mutect2, varscan2
- TMEM69 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs1218474153; called by muse, mutect2, varscan2
- TNR | c.1206C>G p.I402M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV99688248, COSV99692064; called by muse, mutect2, varscan2
- TNXB | c.10553C>T p.A3518V (on ENST00000647633; = p.A3271V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as rs2856444; called by muse, mutect2, varscan2
- TNXB | c.7888G>T p.V2630L (on ENST00000647633; = p.V2383L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV64482025; called by muse, mutect2, varscan2
- TOMM20L | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1256378591; called by muse, mutect2, varscan2
- TONSL | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs767568847, COSV68047696; called by muse, varscan2
- TONSL | c.2137C>A p.Q713K | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV68048510; called by muse, mutect2
- TRHDE | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV53841250; called by muse, mutect2, varscan2
- TRIM58 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.139); catalogued as rs761929755, COSV63572621; called by muse, mutect2, varscan2
- TSACC | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 57/230 reads (25%) | catalogued as COSV64086763; called by muse, mutect2, varscan2
- TSKS | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs548654975; called by muse, mutect2, varscan2
- TTLL5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54039620; called by muse, mutect2, varscan2
- TTN | c.81841G>T p.E27281* (on ENST00000591111; = p.E19857* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 46/143 reads (32%) | catalogued as COSV60039454, COSV60399477; called by muse, mutect2, varscan2
- TTN | c.75083G>A p.S25028N (on ENST00000591111; = p.S17604N on NM_003319.4) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | PolyPhen possibly damaging (0.811); catalogued as rs727505214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.62G>T p.W21L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV67139256; called by muse, mutect2, varscan2
- TUBGCP2 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs569483386; called by muse, mutect2, varscan2
- TYR | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.265); catalogued as COSV54473673; called by muse, mutect2, varscan2
- UGT2B10 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs1183625802; called by muse, mutect2
- USP35 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV71572612, COSV71572763; called by muse, mutect2, varscan2
- VN1R2 | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs755603462; called by muse, mutect2, varscan2
- VSIG4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as COSV66074333; called by muse, mutect2, varscan2
- WASF2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs775407600, COSV71004909, COSV71005161; called by muse, mutect2, varscan2
- WDR7 | c.2619G>T p.E873D | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54364828; called by muse, mutect2, varscan2
- WIPF1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs199846616; called by muse, mutect2, varscan2
- XIRP2 | c.6557C>G p.S2186W (on ENST00000628543; = p.S2361W on NM_152381.6) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54687532; called by muse, mutect2, varscan2
- ZBBX | c.2129C>A p.S710Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs374887332, COSV56786213; called by muse, mutect2, varscan2
- ZBBX | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs530893088; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 46/186 reads (25%) | catalogued as COSV99648982; called by muse, varscan2
- ZDHHC18 | c.532C>G p.R178G | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100938871; called by muse, mutect2, varscan2
- ZFHX4 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV50668487; called by muse, mutect2, varscan2
- ZFYVE19 | c.1174C>T p.R392* (on ENST00000355341 / NM_001077268.2; = p.R382* on NM_032850.5) | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs779395187; called by muse, mutect2
- ZMYM5 | c.577C>G p.H193D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as rs766469276; called by muse, varscan2
- ZNF334 | c.1253C>G p.S418C | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61618482; called by muse, mutect2, varscan2
- ZNF479 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV58638051; called by muse, mutect2, varscan2
- ZNF536 | c.2095G>C p.G699R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62819204; called by muse, mutect2, varscan2
- ZNF573 | c.991G>C p.E331Q (on ENST00000536220 / NM_001172692.1; = p.E273Q on NM_152360.3) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV59828859; called by muse, mutect2, varscan2
- ZNF611 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs760742029, COSV60542617; called by muse, mutect2, varscan2
- ZNF629 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1230413636, COSV99354794; called by muse, mutect2, varscan2
- ZNF646 | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1478059521; called by muse, mutect2, varscan2
- ZNF764 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as rs1422188711; called by muse, mutect2, varscan2
- ZNF765 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV67182242; called by muse, mutect2, varscan2
- ZNF773 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as rs1250607785; called by muse, mutect2, varscan2
- ZNF800 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV99757723; called by muse, mutect2, varscan2
- ZNF804A | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV56457717; called by muse, mutect2, varscan2
- ZNF883 | c.343C>G p.H115D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71309009; called by muse, mutect2, varscan2
- ZNF91 | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56082783; called by muse, mutect2, varscan2
- ZPLD1 | c.567C>A p.N189K (on ENST00000466937 / NM_001329788.1; = p.N205K on NM_175056.2) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs571453581, COSV60353090; called by muse, mutect2, varscan2
- ABCA9 | c.3454G>C p.V1152L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCB11 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC1 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ABCC2 | c.2184G>C p.K728N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCG8 | c.514del p.Q172Rfs*20 | Frame Shift Del (DEL) | VAF 42/169 reads (25%) | called by mutect2, pindel, varscan2
- AC126283.2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTN4 | c.1268C>G p.S423C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- ACVR2B | c.1529C>G p.S510* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ADAM12 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ADAMDEC1 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAMTS17 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS2 | c.2364C>A p.F788L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ADGRB1 | c.1771T>C p.W591R | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AEBP2 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- AGL | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- AGO3 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHI1 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AHSG | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- AKAP6 | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AKAP6 | c.2957A>G p.H986R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP9 | c.11190G>C p.L3730F (on ENST00000359028; = p.L3706F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKR1A1 | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.200_203del p.V67Efs*7 | Frame Shift Del (DEL) | VAF 29/201 reads (14%) | called by mutect2, pindel, varscan2
- ANGEL2 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANK3 | c.6935C>A p.S2312* | Nonsense Mutation (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- ANKH | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.098); called by muse, mutect2
- ANKIB1 | c.1392C>G p.F464L | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKMY1 | c.1977G>T p.R659S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD11 | c.6652G>C p.E2218Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); called by muse, mutect2
- ANKRD35 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- ANKRD50 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP5M1 | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AQR | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ARHGAP11A | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by mutect2, varscan2
- ARHGAP32 | c.3676C>T p.H1226Y (on ENST00000310343 / NM_001378025.1; = p.H877Y on NM_014715.4) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ARHGEF26 | c.1699A>T p.R567W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ARHGEF7 | c.1593G>A p.M531I (on ENST00000375741 / NM_001113511.2; = p.M353I on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ARID4A | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC9 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ARPP21 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ARRDC4 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ARSH | c.1156C>G p.P386A | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ASH2L | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATF7 | c.1030G>C p.E344Q (on ENST00000548446 / NM_001366555.2; = p.E333Q on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- ATG12 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATG9B | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- ATP2A1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ATP6V1A | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- BAZ2B | c.2722C>G p.Q908E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BCL7A | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, varscan2
- BEND2 | c.734A>T p.N245I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- BEND3 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMP8B | c.954G>A p.W318* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- BPTF | c.3258A>T p.K1086N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BRPF1 | c.1821G>T p.L607F | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTBD7 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C11orf68 | c.218C>G p.S73* (on ENST00000530188; = p.S114* on NM_031450.4) | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- C1orf198 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf21 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.965); called by muse, mutect2
- C2orf16 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3orf14 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- C5orf38 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); called by muse, mutect2
- CACNA1D | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CACNA1E | c.6875G>T p.G2292V (on ENST00000367573 / NM_001205293.3; = p.G2249V on NM_000721.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CACNA1F | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CACNA1I | c.1878G>A p.W626* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMKK1 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP2 | c.787C>T p.H263Y (on ENST00000236925 / NM_001297707.2; = p.H252Y on NM_203459.3) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CAPN12 | c.1920G>A p.M640I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.777); called by muse, varscan2
- CAPN2 | c.730-1G>C p.X244_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2
- CARD6 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CC2D2A | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC39 | c.566G>C p.R189T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CCDC7 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CCDC88A | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163 | c.2408G>A p.W803* | Nonsense Mutation (SNP) | VAF 98/231 reads (42%) | called by muse, mutect2, varscan2
- CD226 | c.95A>T p.N32I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CDC123 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CDH11 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- CDH6 | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH9 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 62/474 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CDIP1 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, varscan2
- CDK12 | c.3787G>A p.E1263K (on ENST00000447079 / NM_016507.4; = p.X1254_splice on NM_015083.3) | Missense Mutation (SNP) | VAF 125/348 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CDK8 | c.1324C>G p.Q442E | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CDKAL1 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEMIP | c.1904C>G p.S635C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2
- CEP164 | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CHRFAM7A | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- CHRNB2 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CHRNG | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- CLASRP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.2); called by muse, mutect2, varscan2
- CLDND2 | c.333G>C p.L111F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- CLSPN | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CNOT1 | c.6581C>G p.S2194C | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTLN | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 75/175 reads (43%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- COG8 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- COL14A1 | c.2584G>T p.V862F | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- COL1A2 | c.2993C>G p.P998R | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.65); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- COL22A1 | c.4238C>A p.P1413H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL4A3 | c.260C>A p.T87K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- CPSF2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CPSF3 | c.1227G>C p.L409F | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CREG1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- CRYBB1 | c.524G>C p.W175S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CSMD2 | c.6179G>C p.S2060T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUBN | c.8218A>T p.T2740S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CYFIP2 | c.2542A>G p.M848V (on ENST00000616178 / NM_001291722.2; = p.M823V on NM_014376.4) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CYP2C9 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CYP2U1 | c.1583T>C p.F528S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, varscan2
- CYYR1 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- DACT1 | c.2398G>C p.D800H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- DAG1 | c.2643G>T p.K881N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DARS2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- DBR1 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDR1 | c.1872G>C p.V624= (on ENST00000324771; = p.V587= on NM_001954.4) | Splice Region (SNP) | VAF 28/231 reads (12%) | called by muse, mutect2, varscan2
- DDX60L | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- DENND3 | c.2285G>C p.R762T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DENND4B | c.2578G>C p.E860Q | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DGKG | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- DHX57 | c.2125del p.S709Qfs*30 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIO1 | c.604C>A p.Q202K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRT1 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DNAH10 | c.3082C>G p.Q1028E (on ENST00000409039; = p.Q967E on NM_207437.3) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.11123C>A p.S3708* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | called by muse, varscan2
- DNASE1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- DOCK7 | c.2866G>T p.D956Y (on ENST00000635253 / NM_001367561.1; = p.D925Y on NM_033407.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DOP1B | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DPPA2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DRC1 | c.1279C>G p.H427D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2
- DUSP1 | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2I2 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- DYSF | c.1179G>C p.Q393H | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- ECT2 | c.1111C>G p.L371V (on ENST00000392692 / NM_001349098.2; = p.L340V on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- EDC4 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- EFTUD2 | c.2421G>C p.Q807H | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- EGFLAM | c.2565G>C p.K855N (on ENST00000354891 / NM_001205301.2; = p.K847N on NM_152403.4) | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EHBP1L1 | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.1583C>A p.S528Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- EHD3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ELOA | c.907A>G p.K303E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- EMILIN2 | c.2156T>A p.I719N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ENGASE | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ENGASE | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPHA6 | c.2201G>T p.G734V (on ENST00000389672 / NM_001080448.3; = p.G126V on NM_173655.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPRS1 | c.2090G>T p.C697F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ERN1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- EXD1 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- FAM120B | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- FAM135B | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FAM160B1 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FAM83B | c.2254A>G p.N752D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM90A1 | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FANCM | c.3983_3995del p.F1328Cfs*6 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- FASTKD1 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- FAT4 | c.5747T>C p.V1916A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO43 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- FBXO43 | c.761A>C p.Q254P | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FBXO8 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- FBXO8 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FCRL3 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- FERMT1 | c.364A>G p.S122G | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIBCD1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- FIG4 | c.2151A>T p.K717N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- FIGNL1 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- FLG | c.7114G>A p.E2372K | Missense Mutation (SNP) | VAF 113/544 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FLG2 | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 144/511 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FN1 | c.6653G>C p.G2218A (on ENST00000359671 / NM_001365524.2; = p.G2187A on NM_002026.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRYL | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.159); called by muse, varscan2
- FUT6 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FYCO1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- GABRA2 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- GAK | c.2392C>T p.Q798* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- GALNTL5 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- GCC2 | c.4717G>C p.D1573H | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- GK | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.021); called by muse, mutect2
- GLI1 | c.6C>G p.F2L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GLI1 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- GLMN | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GNA12 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GNAS | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GOLGB1 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GOLGB1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GOT2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GPR137B | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.544); called by muse, mutect2
- GPR139 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GPR158 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- GPR179 | c.684G>C p.R228S | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- GPR37 | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRM3 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRM7 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- H1-6 | c.270C>G p.S90R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- H2AC14 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HADHA | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- HDLBP | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- HEATR5A | c.4532G>A p.W1511* | Nonsense Mutation (SNP) | VAF 49/143 reads (34%) | called by muse, mutect2, varscan2
- HEMK1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HLA-A | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-DRA | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMBOX1 | c.1014G>C p.K338N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HMCN1 | c.5684G>A p.R1895K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HNRNPA3 | c.529C>G p.H177D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HOOK2 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HRH1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HTT | c.5957G>A p.G1986E | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICE1 | c.4354C>T p.Q1452* | Nonsense Mutation (SNP) | VAF 53/160 reads (33%) | called by muse, mutect2, varscan2
- IFNGR1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- IGDCC4 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- IGF2R | c.4382G>A p.C1461Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2R | c.5126G>T p.G1709V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-17 | c.9G>C p.M3I | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, varscan2
- IKZF3 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IL16 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IMPDH1 | c.274C>T p.H92Y (on ENST00000470772 / NM_001142573.2; = p.H177Y on NM_000883.4) | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- INPP4B | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- IQGAP1 | c.3011C>G p.S1004C | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- IRF2BP1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ITGA2 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ITGAX | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ITSN2 | c.1644G>C p.Q548H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KANK4 | c.1732C>A p.L578M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KANK4 | c.1731C>A p.C577* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- KANSL1 | c.2005C>G p.L669V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH8 | c.3236C>A p.S1079* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- KCNK16 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KCTD16 | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- KDF1 | c.1136C>G p.S379* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- KDM1A | c.1661A>G p.Q554R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1109 | c.13753G>A p.D4585N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF19 | c.722T>G p.V241G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- KIF26A | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KIRREL2 | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- KL | c.2906T>C p.V969A | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLHL20 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- KMT2C | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KMT2D | c.9085G>T p.E3029* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- KNTC1 | c.6405G>T p.K2135N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KRTAP26-1 | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KRTAP27-1 | c.357A>T p.E119D | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LEPR | c.977G>C p.R326P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- LGR5 | c.1771C>A p.P591T | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- LILRA6 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LIPJ | c.599T>A p.F200Y | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRP2 | c.8681A>G p.D2894G | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC7 | c.1404G>T p.Q468H (on ENST00000651989 / NM_001370785.2; = p.Q435H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRN4 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MAN1A1 | c.912A>T p.K304N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAN1A2 | c.1637A>T p.H546L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MAP10 | c.2426G>C p.R809T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- MAP3K10 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- MAP4K1 | c.476C>G p.S159W | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 86/199 reads (43%) | called by mutect2, pindel, varscan2
- MAPK4 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MASP2 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MB | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- MBD1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MBD5 | c.3127G>C p.E1043Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MCHR2 | c.72dup p.A25Cfs*45 | Frame Shift Ins (INS) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- MCUR1 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); called by muse, mutect2
- MDC1 | c.5785G>A p.D1929N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MEAK7 | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MEGF10 | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MERTK | c.2717G>A p.C906Y | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MIA3 | c.3018G>C p.M1006I | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MLLT10 | c.1993C>T p.Q665* (on ENST00000307729 / NM_001195626.3; = p.Q681* on NM_004641.3) | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- MME | c.1715C>G p.S572* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- MMP9 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MRC2 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MROH9 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MRPL11 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- MRPS5 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2
- MRS2 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MTHFSD | c.124-2A>G p.X42_splice (on ENST00000360900 / NM_001159377.2; = p.X41_splice on NM_022764.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.23984C>T p.S7995F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- MUC4 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MXI1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); called by muse, varscan2
- MYBPC1 | c.2852C>T p.T951I (on ENST00000550270 / NM_206820.2; = p.T958I on NM_002465.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MYO3A | c.1708A>C p.N570H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MYT1L | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- N4BP2L2 | c.2715G>T p.K905N (on ENST00000674422; = p.K476N on NM_033111.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NACC1 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBPF1 | c.2164G>C p.E722Q | Missense Mutation (SNP) | VAF 82/562 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, varscan2
- NCAPD2 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NCKAP5L | c.2399C>G p.S800* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- NCOA7 | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- NCOR1 | c.5857C>G p.Q1953E | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NCOR1 | c.5716G>A p.D1906N | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- NDN | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NDUFAF4 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- NFKB1 | c.2380G>A p.E794K (on ENST00000394820 / NM_001382627.1; = p.E795K on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRX1 | c.1905C>G p.N635K | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOS3 | c.3612A>G p.*1204Wext*60 | Nonstop Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- NOX4 | c.1136-1G>C p.X379_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- NPLOC4 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- NPR3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPY2R | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NQO2 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NT5DC1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUAK1 | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.10906G>C p.E3636Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR10G7 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- OR10H2 | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR10J1 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- OR10Q1 | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR11L1 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR11L1 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); called by muse, varscan2
- OR12D2 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2A4 | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T3 | c.646A>C p.I216L | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR3A3 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR4M1 | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 55/392 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR51F1 | c.807G>C p.L269F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR52N1 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- OR5AR1 | c.670G>C p.A224P | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- OR6K6 | c.800C>A p.T267N (on ENST00000368144; = p.T243N on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR7E24 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- OR8D4 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.104); called by muse, varscan2
- OR8H2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR9G4 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ORC5 | c.674T>A p.L225H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- P2RY2 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PAIP1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2
- PAK1 | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PAQR3 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PARM1 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PCDH15 | c.3810C>G p.I1270M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHB9 | c.1876A>T p.T626S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PCDHGB4 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PDE9A | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PEAK3 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PEG3 | c.3771G>C p.Q1257H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PER2 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PEX1 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHACTR4 | c.608C>G p.S203C (on ENST00000373839 / NM_001350159.2; = p.S213C on NM_023923.4) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PIBF1 | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PIGR | c.1347G>A p.W449* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- PIK3C3 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIKFYVE | c.3449G>T p.R1150I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PKHD1 | c.9586G>T p.V3196L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.4671T>A p.N1557K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PKNOX2 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLBD1 | c.441del p.N149Ifs*17 | Frame Shift Del (DEL) | VAF 35/139 reads (25%) | called by mutect2, pindel, varscan2
- PLCH1 | c.427C>T p.H143Y (on ENST00000340059 / NM_001130960.2; = p.H155Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PLD2 | c.490-1G>C p.X164_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- PLIN1 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PLXND1 | c.3096C>G p.I1032M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP3 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- POP7 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 126/235 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- POTEF | c.250G>T p.G84* | Nonsense Mutation (SNP) | VAF 45/375 reads (12%) | called by muse, mutect2, varscan2
- POU6F2 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIP5K1 | c.4060C>G p.H1354D (on ENST00000396923; = p.H1329D on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1CB | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPP2R5A | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- PPP6R3 | c.950A>T p.H317L | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- PPY | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM5 | c.1400A>T p.N467I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PRIMPOL | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKCZ | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PROC | c.1356G>C p.K452N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PRPS2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSKH1 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- PTGER4 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PTRH2 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.237); called by muse, mutect2
- PURG | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PXDN | c.2476G>C p.D826H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QSER1 | c.3899C>T p.S1300L (on ENST00000399302; = p.S1429L on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- R3HDM1 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- RAB18 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | called by muse, varscan2
- RAB6D | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RALGPS2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RASAL2 | c.3394G>A p.G1132S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASSF8 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RET | c.2473G>T p.G825C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RFC1 | c.2636C>G p.S879* (on ENST00000381897 / NM_001363496.2; = p.S878* on NM_002913.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- RGP1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- RIF1 | c.972G>C p.L324F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- RIF1 | c.3112G>T p.E1038* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- RILPL1 | c.616C>G p.H206D | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RIMBP2 | c.973G>C p.G325R | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- RLN1 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- RMC1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- RNF111 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- RNF213 | c.1517G>C p.R506T | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.2010G>C p.Q670H | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RNF6 | c.1163C>G p.S388* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- RNLS | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RPAP1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RPGRIP1L | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- RRAGD | c.843A>T p.Q281H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RRP1B | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2
444 further variants in this file (128 protein-altering or splice-affecting, 290 silent, 26 other) are not listed here.
